Somatic mutation profile of tumor specimen TCGA-V4-A9EY-01A (aliquot TCGA-V4-A9EY-01A-11D-A39W-08) from TCGA case TCGA-V4-A9EY, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.2 years (24,187 days).
Specimen TCGA-V4-A9EY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f96c3b2-6ddb-4d34-9283-e8c81518ebd0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EY-10A (Blood Derived Normal), aliquot TCGA-V4-A9EY-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9232055a-80bf-4d3e-bf9e-6f07eb619663

The open-access MAF lists 12 somatic variants for this specimen: 12 protein-altering or splice-affecting.
By variant classification: Missense Mutation 11, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 46/110 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV63309305, COSV63309328; called by muse, mutect2, varscan2
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 57/104 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.1774T>G p.L592V | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as CD130075; called by muse, mutect2, varscan2
- PTGER2 | c.52T>C p.W18R | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.047); catalogued as rs770164807; called by muse, mutect2, varscan2
- SHPK | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.456); catalogued as rs762096736, COSV56650840; called by muse, mutect2, varscan2
- AMOTL2 | c.2323G>A p.V775M (on ENST00000422605; = p.V776M on NM_016201.4) | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARPC2 | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DNAJC8 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ELMO2 | c.571C>G p.Q191E | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- EPC2 | c.1607A>G p.Q536R | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- HUWE1 | c.7240_7242del p.E2414del | In Frame Del (DEL) | VAF 14/56 reads (25%) | called by pindel, varscan2
- RASL12 | c.664A>C p.N222H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); called by muse, mutect2
